Somatic mutation profile of tumor specimen 0DSTYH from CCDI case PBCIRI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 0.1 years (19 days).
Specimen 0DSTYH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5720bfae-12a2-44f3-92cb-106ac6961e35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSTY8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e07bf7b-fbc6-4934-ba1e-737dc2164ff1

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBX15 | c.373C>T p.R125W (on ENST00000369429 / NM_001330677.2; = p.R19W on NM_152380.3) | Missense Mutation (SNP) | VAF 24/512 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751637190, COSV52871120; called by muse, mutect2
